Somatic mutation profile of tumor specimen TARGET-40-PANZZJ-01A (aliquot TARGET-40-PANZZJ-01A-01Y) from TARGET case TARGET-40-PANZZJ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 18.8 years (6,855 days).
Specimen TARGET-40-PANZZJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d20a2e10-0532-415c-b29f-9d547b1289b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PANZZJ-10A (Blood Derived Normal), aliquot TARGET-40-PANZZJ-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35a69f1d-6c58-4028-af7f-c8cc784f0b95

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 3, RNA 3, Frame Shift Del 1, 5'UTR 1, Splice Site 1, 3'UTR 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GALT5 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.618); catalogued as COSV58198771; called by mutect2, varscan2
- CCDC144A | c.1690A>G p.R564G | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs964918116; called by muse, mutect2, varscan2
- GJA3 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1338764977; called by muse, varscan2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs776023104; called by pindel, varscan2
- KIAA0586 | c.1693A>G p.K565E (on ENST00000619416 / NM_001244190.2; = p.K633E on NM_001244189.2) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1297075839; called by mutect2, varscan2
- PRRC1 | c.326A>G p.H109R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.039); catalogued as rs1299030574; called by muse, mutect2, varscan2
- SIL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs55660322, COSV99498533; called by muse, mutect2, varscan2
- SYNE2 | c.8968G>A p.A2990T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs748085293, COSV59947376; called by muse, mutect2, varscan2
- VCAN | c.5347G>A p.E1783K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as COSV54108184; called by muse, mutect2, varscan2
- BMP5 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLCA2 | c.653T>A p.I218N | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- DCAF1 | c.3206G>A p.G1069E | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GALNT15 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- LCE3A | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- MUC16 | c.4345G>T p.E1449* | Nonsense Mutation (SNP) | VAF 68/340 reads (20%) | called by muse, mutect2, varscan2
- MYH7 | c.4962G>T p.Q1654H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYL4 | c.86C>A p.P29Q | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.078); called by mutect2, varscan2
- NUMBL | c.1003C>A p.Q335K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- PRKCB | c.548T>A p.L183H | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF19A | c.759C>G p.H253Q | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- RTN4IP1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- SERPINA10 | c.718G>C p.G240R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPICE1 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2
- TEK | c.1489+1G>C p.X497_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- ZNF492 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FCGBP | c.10539C>G p.T3513= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- GRK3 | c.1830A>G p.E610= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs779602709; called by muse, mutect2, varscan2
- TAP2 | c.672G>T p.R224= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100886949; called by muse, mutect2
- AC005524.1 | n.366C>A | RNA (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- AC073310.1 | n.639A>G | RNA (SNP) | VAF 11/69 reads (16%) | catalogued as rs1171627620; called by muse, mutect2, varscan2
- FIS1 | c.-150G>T | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- PIK3C2G | c.*80G>T | 3'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2
- SNORD115-21 | chr15:25209846 C>A | 3'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- STAG3L3 | n.129del | RNA (DEL) | VAF 8/29 reads (28%) | catalogued as rs1395709145; called by mutect2, varscan2
